Somatic mutation profile of tumor specimen TCGA-BR-4187-01A (aliquot TCGA-BR-4187-01A-01D-1126-08) from TCGA case TCGA-BR-4187, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; Tumor grade: G3; Age at diagnosis: 56.5 years (20,635 days).
Specimen TCGA-BR-4187-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc1f636d-6620-4aac-8bea-2c81a4a0d551.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4187-11A (Solid Tissue Normal), aliquot TCGA-BR-4187-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee08b83c-13be-4a5c-a93e-6976c7ddb890

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Ins 1, Frame Shift Del 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCKDK | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs768986355, COSV54892786; called by muse, mutect2, varscan2
- EFCAB7 | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV64314936; called by muse, mutect2
- FRMPD1 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as rs867293157, COSV63383600; called by muse, mutect2
- HDC | c.1060A>G p.S354G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.999); catalogued as COSV51073765; called by muse, mutect2, varscan2
- OR2J3 | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs1034931465, COSV65849289, COSV65849298; called by muse, mutect2
- PCDHA13 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs782379771, COSV56520410; called by muse, mutect2, varscan2
- PLB1 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780761178, COSV59819843, COSV59822334; called by mutect2, varscan2
- PPT2 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52998880; called by muse, mutect2, varscan2
- RGS11 | c.934G>A p.V312M (on ENST00000397770 / NM_183337.3; = p.V291M on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs746233784, COSV51453134; called by mutect2, varscan2
- RPS6KA2 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs145694057; called by mutect2, varscan2
- SLC9A6 | c.736G>T p.V246F | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV65787762, COSV65787863, COSV65788391; called by muse, mutect2, varscan2
- USH2A | c.7525C>T p.R2509W | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1394948601, COSV56357291, COSV56362607; called by muse, mutect2, varscan2
- ZFC3H1 | c.3823C>A p.H1275N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV66433965; called by muse, mutect2, varscan2
- CDH1 | c.659_663delinsCA p.L220_D221delinsP | In Frame Del (DEL) | VAF 12/55 reads (22%) | called by pindel, varscan2*
- PIGR | c.138dup p.V47Cfs*15 | Frame Shift Ins (INS) | VAF 7/65 reads (11%) | called by mutect2, pindel, varscan2
- UBXN7 | c.332del p.F111Sfs*15 | Frame Shift Del (DEL) | VAF 12/130 reads (9%) | called by mutect2, pindel
- ASTN1 | c.981C>T p.S327= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV56074930; called by muse, mutect2, varscan2
- SOX6 | c.2241C>T p.I747= (on ENST00000528429 / NM_001145819.2; = p.I720= on NM_017508.3) | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV57050498; called by muse, mutect2, varscan2
- TAF1L | c.4860C>T p.Y1620= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV54264358; called by muse, mutect2
- TNN | c.177C>T p.D59= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs1486820822, COSV53421415, COSV53429582; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 6/47 reads (13%) | catalogued as rs201441562; called by pindel, varscan2
